Somatic mutation profile of tumor specimen TCGA-CD-5804-01A (aliquot TCGA-CD-5804-01A-12D-2053-08) from TCGA case TCGA-CD-5804, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CD-5804-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51ae553d-bef9-4ed6-b3d1-454e2da70ac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5804-10A (Blood Derived Normal), aliquot TCGA-CD-5804-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf5128cb-6d1d-49ae-b64c-ed6e3990789e

The open-access MAF lists 86 somatic variants for this specimen: 65 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Splice Site 6, Nonsense Mutation 3, Splice Region 2, In Frame Del 2, Frame Shift Del 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767342, CM100517, COSV61684465, COSV61684539, COSV61685012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.3001C>T p.R1001* (on ENST00000506720 / NM_001322402.2; = p.R933* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV72229067, COSV72230261; called by muse, mutect2, varscan2
- AP4M1 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.08); catalogued as rs762494123, COSV57995750; called by muse, mutect2, varscan2
- C3orf22 | c.21G>C p.K7N | Missense Mutation (SNP) | VAF 125/284 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV59072699; called by muse, mutect2, varscan2
- CDH10 | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1225345022, COSV52577888, COSV52584598; called by muse, mutect2
- CHD3 | c.4287G>A p.M1429I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57874258; called by muse, mutect2, varscan2
- CNTNAP2 | c.1570A>C p.I524L | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV62168840; called by muse, mutect2, varscan2
- COL15A1 | c.3559G>A p.D1187N | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs186296440, COSV66643602; called by muse, mutect2, varscan2
- COL8A1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs755896312, COSV53732750; called by muse, mutect2, varscan2
- DIAPH2 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.415); catalogued as COSV61266310; called by muse, mutect2, varscan2
- DNAH5 | c.10611G>T p.E3537D | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as COSV54218767; called by muse, mutect2, varscan2
- DNAH9 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs200171758, COSV52339977; called by muse, mutect2, varscan2
- EIF2B2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1204906412, COSV56720203; called by muse, mutect2
- ELP1 | c.3348C>T p.A1116= | Splice Region (SNP) | VAF 8/61 reads (13%) | catalogued as COSV65897237; called by muse, mutect2, varscan2
- FBXO7 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.152); catalogued as COSV56677490, COSV56680927; called by muse, mutect2, varscan2
- GABRB3 | c.1245C>G p.F415L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54660232, COSV54680371; called by muse, mutect2, varscan2
- GALNT17 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1315864683, COSV61149103, COSV61154984; called by muse, varscan2
- GPR161 | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54789457; called by muse, mutect2, varscan2
- HAS1 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.45); catalogued as COSV55787054; called by muse, mutect2
- IRS1 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as COSV59335492; called by muse, mutect2, varscan2
- JAK3 | c.1159A>G p.N387D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs745373403, COSV71685931; called by muse, mutect2, varscan2
- KAZN | c.1047+1G>A p.X349_splice | Splice Site (SNP) | VAF 25/139 reads (18%) | catalogued as COSV63207671; called by muse, mutect2, varscan2
- KL | c.2891C>A p.P964Q | Missense Mutation (SNP) | VAF 220/323 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV66308523; called by muse, mutect2, varscan2
- LAMA4 | c.1154T>C p.V385A (on ENST00000230538 / NM_001105206.3; = p.V378A on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV57895490; called by muse, mutect2, varscan2
- LINGO2 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV58059069; called by muse, mutect2, varscan2
- MAP2 | c.3718G>C p.E1240Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.998); catalogued as rs777899876, COSV52288151, COSV52302510; called by muse, mutect2, varscan2
- MAP3K15 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs1235750422, COSV58828617; called by muse, mutect2, varscan2
- MDGA2 | c.2989+1G>A p.X997_splice (on ENST00000399232 / NM_001113498.2; = p.X699_splice on NM_182830.4) | Splice Site (SNP) | VAF 21/53 reads (40%) | catalogued as COSV62087495; called by muse, mutect2, varscan2
- MICAL2 | c.4988G>A p.R1663K | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV56285502; called by muse, mutect2, varscan2
- MIPEP | c.1684T>G p.C562G | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV66300332; called by muse, mutect2, varscan2
- NDUFAF5 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV65246828; called by muse, mutect2
- NIN | c.4838G>A p.R1613H (on ENST00000382041 / NM_182946.1; = p.R900H on NM_016350.4) | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs200205970, COSV55387284; called by muse, mutect2, varscan2
- PANX2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.701); catalogued as rs139331786; called by muse, mutect2, varscan2
- PCDHA6 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65350562; called by muse, mutect2, varscan2
- PCDHB14 | c.1198T>A p.F400I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs1554289223, COSV53387937; called by muse, mutect2, varscan2
- PLXNB2 | c.400T>A p.Y134N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV63781104; called by muse, mutect2, varscan2
- PRKCQ | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1274566995, COSV54106426; called by muse, mutect2, varscan2
- PWWP2B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1189428914, COSV59450000; called by muse, mutect2, varscan2
- PXDNL | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs773943804, COSV62485576; called by muse, mutect2
- RGS11 | c.1004C>T p.A335V (on ENST00000397770 / NM_183337.3; = p.A314V on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99395874; called by mutect2, varscan2
- RGS6 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as rs200924429, COSV59573357; called by muse, mutect2, varscan2
- RPL26 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs752268233, COSV53446950; called by muse, mutect2, varscan2
- RSKR | c.408G>A p.K136= | Splice Region (SNP) | VAF 7/73 reads (10%) | catalogued as COSV56381675; called by muse, mutect2
- SCGB1D4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as rs149931773, COSV62203927, COSV62203971; called by muse, mutect2, varscan2
- SHANK1 | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1229197601, COSV53247892; called by muse, mutect2, varscan2
- SLC12A1 | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57709111; called by muse, mutect2, varscan2
- SPATA31A1 | c.3667C>G p.L1223V | Missense Mutation (SNP) | VAF 39/434 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.31); catalogued as rs1411533004; called by muse, mutect2, varscan2
- STK32A | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60417484; called by muse, mutect2, varscan2
- TMEM132D | c.3148T>C p.F1050L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs755320363, COSV67159899; called by muse, mutect2, varscan2
- TTC17 | c.3359C>T p.P1120L | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs757564706, COSV50007855; called by muse, mutect2, varscan2
- TTPA | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1233515069, COSV52646372, COSV99478567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP36 | c.3064del p.E1022Sfs*22 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | catalogued as COSV100361534; called by mutect2, pindel, varscan2
- USPL1 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.536); catalogued as COSV54999582; called by muse, mutect2
- VCPIP1 | c.454A>T p.M152L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.558); catalogued as rs761512948, COSV60046768; called by muse, mutect2, varscan2
- WNK2 | c.6218G>A p.R2073H (on ENST00000297954 / NM_001282394.1; = p.R2036H on NM_006648.3) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs776503070, COSV52938847; called by mutect2, varscan2
- ZYG11B | c.1485+2T>C p.X495_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV53752204; called by muse, mutect2, varscan2
- AGRN | c.502_511+8del p.X168_splice | Splice Site (DEL) | VAF 23/232 reads (10%) | called by mutect2, pindel
- MYL6 | c.429_439del p.X143_splice | Splice Site (DEL) | VAF 34/208 reads (16%) | called by mutect2, pindel, varscan2
- NIBAN3 | c.517_520+10del p.X173_splice | Splice Site (DEL) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- PDE1B | c.1177_1179del p.F393del | In Frame Del (DEL) | VAF 24/131 reads (18%) | called by pindel, varscan2
- PIGA | c.1019_1048del p.L340_E349del | In Frame Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel
- PRAMEF4 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SALL1 | c.1437_1447del p.C479Wfs*33 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- ZNF140 | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- BMP7 | c.1125C>T p.N375= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV67780409, COSV99060158; called by muse, varscan2
- CBFA2T2 | c.1572G>A p.A524= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs150139351; called by muse, mutect2, varscan2
- CCKAR | c.1006C>A p.R336= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV55161035; called by muse, mutect2, varscan2
- CHD7 | c.5034C>T p.A1678= | Silent (SNP) | VAF 45/270 reads (17%) | catalogued as COSV71109319; called by muse, mutect2, varscan2
- COL12A1 | c.7296C>A p.V2432= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV59394102; called by muse, mutect2, varscan2
- COL17A1 | c.1080G>T p.L360= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as COSV62226392; called by muse, mutect2, varscan2
- CYP4F2 | c.1428G>A p.A476= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV55616254; called by muse, mutect2, varscan2
- DCANP1 | c.501C>T p.S167= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs372001818; called by muse, mutect2, varscan2
- DNAH3 | c.3537C>T p.N1179= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs768318201, COSV54516365; called by muse, mutect2, varscan2
- EHHADH | c.984G>A p.S328= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs372621913, COSV51629357; called by muse, mutect2, varscan2
- FAT3 | c.6585C>T p.V2195= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53100044; called by muse, mutect2, varscan2
- GPX6 | c.147C>T p.N49= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs767523979, COSV62657330, COSV62659016; called by muse, mutect2, varscan2
- HSDL2 | c.1062G>T p.G354= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV52714503; called by muse, mutect2, varscan2
- MOGAT3 | c.315G>A p.P105= | Silent (SNP) | VAF 17/155 reads (11%) | catalogued as rs753702249, COSV56173909; called by muse, mutect2, varscan2
- OR4K1 | c.456C>T p.G152= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs762768302, COSV53459799; called by muse, mutect2, varscan2
- PCDHB10 | c.1341C>T p.N447= | Silent (SNP) | VAF 42/203 reads (21%) | catalogued as rs746631503, COSV53377853; called by muse, mutect2, varscan2
- RYR1 | c.1002C>T p.G334= | Silent (SNP) | VAF 15/162 reads (9%) | catalogued as COSV62094961; called by muse, mutect2
- UBAC1 | c.504G>A p.A168= | Silent (SNP) | VAF 23/126 reads (18%) | catalogued as rs775731673, COSV100873836, COSV65614031; called by muse, mutect2, varscan2
- ZC3H7B | c.2562G>A p.K854= | Silent (SNP) | VAF 23/151 reads (15%) | catalogued as COSV60961518; called by muse, mutect2, varscan2
- AC244258.1 | n.971G>T | RNA (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- CADM2 | c.62-75501A>C | Intron (SNP) | VAF 31/124 reads (25%) | catalogued as COSV101057186, COSV67388279; called by muse, mutect2, varscan2
